Somatic mutation profile of tumor specimen 0E0MJ7 from CCDI case PBCVGK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0MJ7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fefe3b3-ee75-4fc3-9f19-23a086688330.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0MJX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fad7c24-9cf6-4f96-a4f3-eb34740e428b

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, 5'UTR 5, Silent 3, Nonsense Mutation 2, Intron 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP4 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 153/917 reads (17%) | catalogued as rs387906597, CM091519, COSV55415575; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 258/1278 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201599169, COSV66065604; ClinVar: uncertain significance / benign; called by muse, varscan2
- ANO7 | c.1243G>A p.G415S (on ENST00000274979; = p.G361S on NM_001370694.2) | Missense Mutation (SNP) | VAF 92/478 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.503); catalogued as rs772860631; called by muse, mutect2, varscan2
- CD163L1 | c.873G>C p.W291C | Missense Mutation (SNP) | VAF 136/807 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58026406; called by muse, mutect2, varscan2
- CEP250 | c.5605C>T p.R1869* | Nonsense Mutation (SNP) | VAF 177/949 reads (19%) | catalogued as rs1185745994; called by muse, mutect2, varscan2
- CREB3L2 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 250/1645 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs778038461, COSV57794142; called by muse, mutect2, varscan2
- DEPTOR | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 217/965 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as rs759755175, COSV53815248; called by muse, mutect2, varscan2
- ERICH3 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 154/797 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.286); catalogued as rs748670801, COSV100445650, COSV58605635; called by muse, mutect2, varscan2
- GIMAP1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 160/853 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs781514490, COSV56187895; called by muse, mutect2, varscan2
- JAG2 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 148/875 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs748673922; called by muse, varscan2
- SAFB | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 96/510 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as rs561011464, COSV52651108; called by muse, mutect2, varscan2
- WDR49 | c.593T>A p.M198K (on ENST00000308378 / NM_001366158.1; = p.M539K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 343/1296 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1375456329; called by muse, mutect2, varscan2
- CACNA1A | c.6082A>C p.S2028R | Missense Mutation (SNP) | VAF 166/817 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 61/1600 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CLCN6 | c.2201A>G p.E734G | Missense Mutation (SNP) | VAF 203/1155 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- COQ10A | c.110_112del p.P37del | In Frame Del (DEL) | VAF 65/419 reads (16%) | called by mutect2, varscan2
- CYP4X1 | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 189/917 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, varscan2
- DNAH1 | c.11449C>A p.L3817M | Missense Mutation (SNP) | VAF 221/1215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- EXOSC10 | c.102C>A p.S34R | Missense Mutation (SNP) | VAF 177/963 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- HMOX2 | c.280T>C p.F94L | Missense Mutation (SNP) | VAF 126/887 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- PKD1 | c.1783G>T p.G595W | Missense Mutation (SNP) | VAF 95/1662 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- SLC39A2 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 205/1128 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPTA1 | c.6136G>C p.V2046L | Missense Mutation (SNP) | VAF 154/992 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WARS2 | c.532G>T p.V178F | Missense Mutation (SNP) | VAF 163/876 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF518A | c.4261G>T p.V1421L | Missense Mutation (SNP) | VAF 247/1066 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- DHH | c.462C>T p.R154= | Silent (SNP) | VAF 94/534 reads (18%) | catalogued as COSV57201788; called by muse, varscan2
- MAGEC1 | c.2916C>T p.D972= | Silent (SNP) | VAF 185/596 reads (31%) | called by muse, mutect2, varscan2
- PIEZO2 | c.1587T>G p.T529= | Silent (SNP) | VAF 392/2222 reads (18%) | called by muse, mutect2, varscan2
- ADGRL4 | c.-40G>A | 5'UTR (SNP) | VAF 249/1230 reads (20%) | catalogued as rs1264072023, COSV66060735; called by muse, mutect2, varscan2
- ADO | c.*28C>G | 3'UTR (SNP) | VAF 69/146 reads (47%) | catalogued as rs770725712; called by muse, mutect2, varscan2
- ATR | c.3725+12G>T | Intron (SNP) | VAF 307/660 reads (47%) | called by muse, mutect2, varscan2
- LGALS4 | c.-6C>G | 5'UTR (SNP) | VAF 117/612 reads (19%) | catalogued as rs199935607, COSV99669403; called by muse, mutect2, varscan2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 20/678 reads (3%) | catalogued as rs926414386, COSV100695372; called by muse, mutect2
- SOWAHA | c.-57G>A | 5'UTR (SNP) | VAF 15/54 reads (28%) | called by muse, varscan2
- STUM | c.-22C>A | 5'UTR (SNP) | VAF 74/535 reads (14%) | called by muse, mutect2, varscan2
